Somatic mutation profile of tumor specimen 392b8aa4-9f99-4250-b693-326260 (aliquot 392b8aa4-9f99-4250-b693-326260_D6_1) from CPTAC case 18BR017, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.5 years (26,492 days).
Specimen 392b8aa4-9f99-4250-b693-326260: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faed6960-4613-4ed5-970d-6dc04e015e0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen f49705bd-129b-4bfe-a944-a7eb51 (Blood Derived Normal), aliquot f49705bd-129b-4bfe-a944-a7eb51_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29c49baa-538d-4eb0-842f-6480ff8c9917

The open-access MAF lists 86 somatic variants for this specimen: 57 protein-altering or splice-affecting, 16 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 16, Intron 7, RNA 3, 3'UTR 2, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AEN | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 125/540 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866947698, COSV60429610; called by muse, mutect2, varscan2
- C1orf116 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760559013; called by muse, mutect2, varscan2
- CCDC120 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs141665638; called by muse, mutect2, varscan2
- CFAP61 | c.1826C>T p.T609I | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as rs1341390178; called by muse, mutect2, varscan2
- CHRNA1 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 140/670 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1019158028, COSV53685188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRMP1 | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs1333537242; called by muse, mutect2, varscan2
- DCAF12L1 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 58/523 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as rs747904012, COSV64421176; called by muse, mutect2, varscan2
- DKK1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 47/402 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs1174106735; called by muse, mutect2, varscan2
- F7 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 52/463 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1269916662, CM010251, CM099563, COSV60644845; called by muse, mutect2
- FBRSL1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs764604501; called by muse, mutect2
- IFT81 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV54360513; called by muse, mutect2
- INPPL1 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 42/468 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs373971775; called by muse, mutect2
- KCNG3 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60150608; called by muse, mutect2, varscan2
- KRT74 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 70/724 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.474); catalogued as rs150958845; called by muse, mutect2
- LAMA4 | c.3308G>A p.R1103H (on ENST00000230538 / NM_001105206.3; = p.R1096H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs782568532; called by muse, mutect2, varscan2
- LCA5L | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780853140, COSV55744844; called by mutect2, varscan2
- LRFN3 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs781141462; called by muse, mutect2, varscan2
- LRRC4B | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65349484; called by muse, mutect2, varscan2
- MAL | c.26dup p.S10Qfs*21 | Frame Shift Ins (INS) | VAF 78/290 reads (27%) | catalogued as rs750821753; called by mutect2, pindel, varscan2
- MTMR4 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 71/358 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.013); catalogued as COSV100050675; called by muse, mutect2, varscan2
- NAPSA | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99515756; called by muse, mutect2, varscan2
- NLRP11 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.301); catalogued as rs747664882, COSV64088204; called by muse, varscan2
- OCA2 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 183/840 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1199627951, COSV62352324; called by muse, mutect2, varscan2
- PCDHA3 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 571/1659 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV100793723, COSV63542265; called by muse, mutect2, varscan2
- PIBF1 | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58328210; called by muse, mutect2, varscan2
- RBM4B | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 44/514 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as COSV100026549; called by muse, mutect2
- RTL9 | c.3811C>T p.R1271W | Missense Mutation (SNP) | VAF 59/464 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1456180070, COSV71825500; called by muse, mutect2, varscan2
- SH3TC2 | c.3833C>T p.A1278V | Missense Mutation (SNP) | VAF 143/419 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as rs374516818; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIGLEC7 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs775681069; called by muse, mutect2, varscan2
- TTN | c.18439G>A p.G6147R (on ENST00000591111; = p.G5220R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/196 reads (18%) | PolyPhen probably damaging (0.944); catalogued as rs755082868, COSV60128494; called by muse, mutect2, varscan2
- WNT6 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1317873348; called by muse, mutect2, varscan2
- ZBTB46 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 39/678 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV55510748; called by muse, mutect2
- ZNF585A | c.1660G>A p.E554K (on ENST00000292841 / NM_001288800.2; = p.E499K on NM_152655.3) | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as rs572122130, COSV53062883; called by muse, mutect2
- ABCC6 | c.1316T>A p.V439D | Missense Mutation (SNP) | VAF 180/504 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ACTR3B | c.107C>G p.A36G | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2
- ANKRD33 | c.35T>A p.V12E (on ENST00000340970 / NM_001304459.2; = p.V147E on NM_182608.4) | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AP3B2 | c.2897T>C p.F966S (on ENST00000261722; = p.F960S on NM_004644.5) | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); called by muse, mutect2
- APOBEC4 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 20/307 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2
- CNR1 | c.1203T>A p.S401R | Missense Mutation (SNP) | VAF 110/469 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CRIP2 | c.406+8C>T | Splice Region (SNP) | VAF 173/631 reads (27%) | called by muse, mutect2, varscan2
- EP400 | c.6570G>T p.E2190D | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM43A | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- FLACC1 | c.734A>T p.K245M | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- INTS6L | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ITGB2 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 78/602 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAMLD1 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 188/879 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, varscan2
- NYAP1 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRKDC | c.11343del p.C3781* | Frame Shift Del (DEL) | VAF 57/209 reads (27%) | called by mutect2, pindel, varscan2
- RIPOR3 | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.264); called by muse, mutect2
- ROBO1 | c.1780T>C p.Y594H | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC30A10 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.102); called by muse, mutect2
- SLC35C2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SLC6A16 | c.1586C>G p.S529C | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TEX13B | c.747C>A p.S249R | Missense Mutation (SNP) | VAF 231/1170 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TMCO4 | c.1040C>G p.S347C | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TUBAL3 | c.266A>G p.Q89R | Missense Mutation (SNP) | VAF 37/668 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- VIPR1 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 42/149 reads (28%) | called by muse, mutect2, varscan2
- BNIP5 | c.1788C>T p.R596= | Silent (SNP) | VAF 53/497 reads (11%) | catalogued as rs752681697, COSV101465143, COSV101465232; called by muse, mutect2, varscan2
- DENND2A | c.2955C>A p.P985= | Silent (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- DOCK2 | c.36C>T p.H12= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as COSV56960932; called by muse, mutect2
- FN1 | c.3468G>A p.L1156= | Silent (SNP) | VAF 22/241 reads (9%) | catalogued as COSV60565348; called by muse, mutect2
- FNDC1 | c.4776C>T p.G1592= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs201671338; called by muse, mutect2, varscan2
- H2BW1 | c.243C>T p.F81= | Silent (SNP) | VAF 24/736 reads (3%) | catalogued as rs782087519; called by muse, mutect2
- HSD17B11 | c.189G>T p.L63= | Silent (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2, varscan2
- KIF1C | c.1143A>T p.G381= | Silent (SNP) | VAF 31/256 reads (12%) | called by muse, mutect2, varscan2
- KRT76 | c.1008G>A p.T336= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs745778936; called by muse, varscan2
- LCE3B | c.153C>T p.G51= | Silent (SNP) | VAF 65/644 reads (10%) | catalogued as rs770470936, COSV59500643; called by muse, mutect2
- OR4C5 | c.759C>T p.C253= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as rs1422713823; called by muse, mutect2, varscan2
- PKD1 | c.1413G>A p.S471= | Silent (SNP) | VAF 140/371 reads (38%) | catalogued as rs868319556; called by muse, mutect2, varscan2
- PPP4C | c.237C>T p.F79= | Silent (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
- SFTPC | c.579G>A p.P193= | Silent (SNP) | VAF 34/750 reads (5%) | catalogued as rs1308709805; called by muse, mutect2
- TMCO4 | c.1080C>A p.L360= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as COSV53876630; called by muse, mutect2, varscan2
- TNFRSF13B | c.696C>T p.F232= | Silent (SNP) | VAF 34/253 reads (13%) | called by muse, mutect2, varscan2
- AC114490.3 | c.*261G>A | 3'UTR (SNP) | VAF 46/142 reads (32%) | called by muse, mutect2, varscan2
- ADGRG4 | c.*23T>C | 3'UTR (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- AZGP1P1 | n.209G>A | RNA (SNP) | VAF 54/452 reads (12%) | called by muse, mutect2, varscan2
- COL4A3 | c.2489-9C>T | Intron (SNP) | VAF 21/88 reads (24%) | catalogued as rs749574789; called by muse, mutect2, varscan2
- LIMS1 | c.-4-4389G>A | Intron (SNP) | VAF 47/342 reads (14%) | catalogued as rs1460750661; called by muse, mutect2, varscan2
- LINC00602 | n.1080G>A | RNA (SNP) | VAF 52/372 reads (14%) | catalogued as rs1205854792; called by muse, mutect2, varscan2
- MYBBP1A | c.3195+10G>A | Intron (SNP) | VAF 102/358 reads (28%) | catalogued as rs199775757, COSV54594396; called by muse, mutect2, varscan2
- OSBPL2 | chr20:62233333 C>T | 5'Flank (SNP) | VAF 18/401 reads (4%) | called by muse, mutect2
- PEX10 | c.601-11C>T | Intron (SNP) | VAF 76/509 reads (15%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.741-2692G>A | Intron (SNP) | VAF 7/77 reads (9%) | catalogued as rs1448546327; called by muse, mutect2, varscan2
- TTC3P1 | n.5759C>T | RNA (SNP) | VAF 79/290 reads (27%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23302C>T | Intron (SNP) | VAF 108/566 reads (19%) | catalogued as COSV59384832; called by muse, mutect2, varscan2
- ZC3H14 | c.80-147T>G | Intron (SNP) | VAF 26/85 reads (31%) | catalogued as rs985844705; called by muse, mutect2, varscan2
